Somatic mutation profile of tumor specimen TARGET-10-PASVIN-09A (aliquot TARGET-10-PASVIN-09A-01D) from TARGET case TARGET-10-PASVIN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,619 days).
Specimen TARGET-10-PASVIN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deb3cd86-0a5e-438a-830a-75d54672fc69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASVIN-10A (Blood Derived Normal), aliquot TARGET-10-PASVIN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6ceaa73-c39d-44c6-9ab5-186c268f3922

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Nonsense Mutation 6, RNA 4, Silent 4, Frame Shift Ins 3, Intron 3, 5'Flank 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>T p.R465L (on ENST00000281708 / NM_001349798.2; = p.R385L on NM_018315.5) | Missense Mutation (SNP) | VAF 9/99 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA10 | c.3956G>A p.S1319N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs11657280; called by muse, mutect2, varscan2
- ABTB1 | c.892C>T p.R298* (on ENST00000232744 / NM_172027.3; = p.R156* on NM_032548.3) | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as rs551191476, COSV51741811; called by muse, mutect2, varscan2
- ADARB2 | c.561G>C p.R187S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV67225257; called by mutect2, varscan2
- DDX3X | c.221_222insGACT p.S75Tfs*2 (on ENST00000399959; = p.S76Tfs*2 on NM_001356.5) | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | catalogued as COSV67863776; called by mutect2, pindel
- FAM193A | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV100218803, COSV61194852; called by muse, mutect2, varscan2
- GJB4 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs375489958; called by muse, mutect2, varscan2
- GRHL2 | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV52549402; called by muse, mutect2, varscan2
- IPO9 | c.1884C>A p.D628E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as COSV64233988; called by muse, mutect2, varscan2
- IQCF1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs145799557; called by muse, mutect2
- KRT34 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV67449938; called by muse, mutect2, varscan2
- MEIS2 | c.976T>G p.W326G (on ENST00000561208 / NM_170675.5; = p.W313G on NM_002399.3) | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54937298; called by muse, mutect2, varscan2
- NOTCH1 | c.7183C>T p.Q2395* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV53056886; called by muse, mutect2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2
- NRXN1 | c.3499C>T p.R1167* | Nonsense Mutation (SNP) | VAF 47/148 reads (32%) | catalogued as rs199546979, COSV58438923, COSV58455553; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDH19 | c.1483T>C p.S495P | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV55264528; called by muse, mutect2, varscan2
- PTEN | c.698_699delinsCCCT p.R233Pfs*24 | Frame Shift Ins (INS) | VAF 9/68 reads (13%) | catalogued as COSV64301438, COSV99058018; called by pindel, varscan2*
- RAB2B | c.180G>C p.W60C | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52969320; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SLITRK4 | c.1376A>T p.N459I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024292; called by muse, mutect2, varscan2
- SMARCA4 | c.3573C>G p.H1191Q | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758326; called by muse, mutect2
- TNC | c.4063G>A p.V1355M | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs569664449, COSV60785672; called by muse, mutect2, varscan2
- ZNF780A | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 39/91 reads (43%) | catalogued as COSV61815605; called by muse, mutect2, varscan2
- DDX3X | c.440+1_440+2insGGGGTGTAG | Nonsense Mutation (INS) | VAF 8/24 reads (33%) | called by pindel, varscan2
- KMT2C | c.8525dup p.N2842Kfs*2 | Frame Shift Ins (INS) | VAF 52/120 reads (43%) | called by mutect2, varscan2
- PIK3R1 | c.1346_1347delinsCCTCGAAC p.L449delinsSSN (on ENST00000521381 / NM_181523.3; = p.L179delinsSSN on NM_181504.4) | In Frame Ins (INS) | VAF 6/38 reads (16%) | called by muse*, pindel
- TPP1 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2
- BHLHE40 | c.1191C>T p.L397= | Silent (SNP) | VAF 80/185 reads (43%) | called by muse, mutect2, varscan2
- CDH10 | c.2235T>G p.A745= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- RPTOR | c.433C>A p.R145= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60817731; called by mutect2, varscan2
- ZNF536 | c.2202C>T p.G734= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs371328800; called by muse, mutect2, varscan2
- BX537318.2 | n.389G>A | RNA (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- EXOC3 | chr5:442390 C>A | 5'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- GP2 | c.94+66C>A | Intron (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- HSPA1A | c.*52T>A | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- HSPA7 | n.318C>T | RNA (SNP) | VAF 40/106 reads (38%) | catalogued as rs753568412; called by muse, mutect2, varscan2
- HYDIN2 | n.13125G>A | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- MCTS1 | c.397-27dup | Intron (INS) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- MEIOC | c.2639-31T>C | Intron (SNP) | VAF 34/116 reads (29%) | catalogued as rs1365152596; called by muse, mutect2, varscan2
- MIR202 | n.20G>A | RNA (SNP) | VAF 30/47 reads (64%) | catalogued as rs568899133; called by muse, varscan2
